Gene-level copy-number profile of specimen HCM-WCMC-0502-C15-85A from HCMI case HCM-WCMC-0502-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.9 years (15,658 days).
Specimen HCM-WCMC-0502-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8bc97a8a-e6ed-4000-be58-a204cc1a0fd1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0502-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/8373dedd-4f88-4649-8082-d2474a87f599

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,315; copy number 2: 30,923; copy number 3: 19,445; copy number 4: 2,664; copy number 5: 1,032; copy number 6: 420; copy number 7: 30; copy number 11: 4; copy number 15: 9; copy number 28: 15; copy number 30: 3; copy number 33: 14; copy number 36: 1; copy number 38: 4; copy number 51: 1; copy number 81: 6; copy number 83: 3; copy number 99: 8; copy number 100: 10.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,560 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:56,147,630–56,386,171, 1 gene, copy number 5 (within-gene range 4–5): AC007744.1.
- chr2:56,183,990–56,750,563, 3 genes, copy number 5 (within-gene range 4–5): CCDC85A, RNA5SP93, PPIAP63.
- chr2:85,315,041–87,825,952, 86 genes, copy number 6 (broad region; genes not listed).
- chr2:236,910,797–237,601,614, 14 genes, copy number 5 (within-gene range 4–5): AC012063.1, RNU6-1051P, AC105760.1, COPS8, AC107079.1, AC112715.1, COL6A3, AC112721.1, AC112721.2, MLPH, MIR6811, RNU6-1140P, PRLH, RAB17.
- chr2:237,627,587–237,842,808, 3 genes, copy number 5: LRRFIP1, AC012076.1, RBM44.
- chr3:10,014,238–10,321,112, 16 genes, copy number 5: CIDECP1, FANCD2, RNU6-670P, CYCSP11, FANCD2OS, BRK1, VHL, AC034193.1, IRAK2, TATDN2, AC022384.1, LINC00852, GHRL, GHRLOS, AC022384.2, SEC13.
- chr3:11,952,788–12,434,356, 8 genes, copy number 5 (within-gene range 3–5): RN7SL147P, SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1.
- chr3:193,144,464–193,844,024, 14 genes, copy number 5: AC092966.1, VEZF1P1, PLAAT1, ATP13A5, ATP13A5-AS1, ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA, RN7SL447P, AC069421.1, LINC02038.
- chr8:264,315–738,106, 9 genes, copy number 5–7: AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1.
- chr8:738,548–1,019,704, 3 genes, copy number 5: AC100797.4, AC026950.2, AC129915.3.
- chr8:68,293,446–70,669,185, 40 genes, copy number 5–7: RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P.
- chr8:110,105,076–133,756,646, 272 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:133,886,496–133,963,259, 3 genes, copy number 5–6: AC110741.1, AC110741.3, AC110741.2.
- chr8:144,772,224–145,066,685, 16 genes, copy number 6–7: ZNF34, RN7SL395P, RPL8, MIR6850, ZNF517, ZNF7, COMMD5, ZNF250, ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr11:31,369,840–41,857,733, 132 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:24,212,421–34,249,958, 211 genes, copy number 5–100 (within-gene range 5–107) (broad region; genes not listed).
- chr18:14,179,097–15,271,744, 39 genes, copy number 5–6: ANKRD20A5P, RNU6-316P, RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005901.2, AP005901.3, BNIP3P3, AP005901.4.
- chr18:75,070,197–75,074,205, 2 genes, copy number 5: AC015819.2, AC015819.1.
- chr18:75,844,925–75,868,252, 1 gene, copy number 5: AC021506.1.
- chr19:19,561,707–19,643,657, 5 genes, copy number 5: PBX4, PHF5CP, AC002306.1, LPAR2, GMIP.
- chr19:19,699,203–20,063,320, 24 genes, copy number 5: AC011458.2, AC011458.1, ZNF14, AC011477.6, AC011477.7, AC011477.5, LINC00663, AC011477.8, AC011477.3, AC011477.4, ZNF56, ZNF506, AC011477.1, BNIP3P9, ZNF253, BNIP3P10, AC011477.2, ZNF93, AC007204.1, AC007204.2, ZNF682, AC006539.2, AC006539.3, BNIP3P13.
- chr19:20,619,939–20,661,596, 1 gene, copy number 5 (within-gene range 4–5): ZNF626.
- chr19:20,746,923–21,569,237, 35 genes, copy number 5–6: AC010329.1, VN1R79P, ZNF66, BNIP3P24, AC008739.2, ZNF85, AC008739.6, KRT18P40, AC008739.1, ZNF430, AC008739.3, VN1R80P, ZNF714, RNA5SP469, VN1R81P, ZNF431, RPL7AP10, VN1R82P, AC010620.1, AC010620.2, RPL36AP51, AC022432.1, VN1R83P, ZNF708, BNIP3P25, ZNF738, AC010615.3, AC010615.1, ZNF493, AC010615.4, AC010615.2, LINC00664, ZNF429, BNIP3P26, AC123912.1.
- chr19:21,932,958–22,261,335, 16 genes, copy number 5: ZNF208, MTDHP2, AC003973.2, BNIP3P28, AC003973.1, ZNF257, BNIP3P29, ZNF92P2, AC073539.2, PCGF7P, MTDHP5, VN1R85P, ZNF676, BNIP3P30, AC073539.1, AC073539.3.
- chr19:22,752,183–22,784,151, 4 genes, copy number 5: ZNF99, AC008626.2, AC008626.1, BNIP3P34.
- chr19:50,968,193–58,605,223, 602 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,459. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
